Surgical pathology report (de-identified scan), TCGA case TCGA-AK-3425, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site Fox Chase, specimen TCGA-AK-3425-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Source of Specimen(s):

A: RENAL TUMOR

B: PARA AORTIC LYMPH NODE LEFT

Other Related Clinical Data:

SURGICAL PATHOLOGY REPORT

Clinical History/Diagnosis: LT RENAL TUMOR

Specimen(s): 1 RENAL TUMOR

2 PARA AORTIC LYMPH NODE LEFT

Sunquest Archived Tests:

NATURE OF SPECIMEN : RESECTION, FROZEN SECTION

Gross Description:

GROSS DESCRIPTION: Received in two parts.

SOURCE OF TISSUE: 1. Labeled #1, "renal tumor"

FROZEN SECTION DIAGNOSIS: 1FS - CLEAR CELL CARCINOMA, PER DR.

GROSS DESCRIPTION: Received fresh for frozen section evaluation is a 1,426

gram nephrectomy having an abundant amount of attached perinephric fat.

The

kidney itself is 9.5 x 7.5 x 5.0 cm in greatest dimension having a 4.5 x 0.2

cm portion of attached ureter, having a lumen, 0.2 cm in greatest dimension,

which is probe patent to the renal pelvis. The kidney is bivalved to reveal

red-purple firm renal parenchyma having a well defined corticomedullary junction. In the mid portion there is a 5.5 x 3.5 x 3.0 cm mass having golden yellow-tan to red-purple, soft, variegated and nodular cut surfaces.

Representative section of this mass are submitted for frozen section evaluation and the frozen section residue is submitted in one block. On sectioning through the perinephric fat there is a 4.5 x 2.0 x 0.5 cm adrenal gland having golden yellow-tan cut surfaces. Representative

[page 2 of 2]
sections are submitted in twelve blocks.

DESIGNATION OF SECTIONS: 1FS - frozen section renal mass, 1A - ureter and vascular margins, 1B-1G - renal mass, 1H-1I - inked circumferential margin, 1J-1K - random kidney sections, 1L - adrenal gland

SUMMARY OF SECTIONS: FS, A-L - multiple

**

*

SOURCE OF TISSUE: 2. Labeled #2, "para-aortic lymph node left"

GROSS DESCRIPTION: Received fresh are 5.5 x 4.0 x 2.0 cm of yellow-tan fibroadipose tissue. It contains several palpable lymph nodes, 0.6 to 2.0

cm in greatest dimension. The lymph nodes are entirely submitted in eight blocks.

DESIGNATION OF SECTIONS: 2A-2H (A-B - one lymph node, C - one lymph node, D - one lymph node, E-G - one lymph node, H - two single lymph nodes)

SUMMARY OF SECTIONS: A-H - multiple

**

*

Final Diagnosis:

DIAGNOSIS:

1. LEFT KIDNEY, NEPHRECTOMY:

- RENAL CELL ADENOCARCINOMA, CLEAR CELL TYPE, INTERMEDIATE GRADE, 5.5CM,

CONFINED TO THE KIDNEY.

- NEGATIVE ADRENAL GLAND.

- TUMOR DOES NOT INVOLVE RENAL VEIN, CAPSULE OR PERIRENAL FAT.

- URETER AND VEIN MARGINS NEGATIVE.

2. LYMPH NODE, PARA-AORTIC, LEFT, EXCISION:

- SIX NEGATIVE LYMPH NODES (0/6).

Source: NCI Genomic Data Commons file 13302a9e-723a-4c16-bd08-f8f187bdaf3b (TCGA-AK-3425.3C0DCC29-86CC-44B2-ABA9-FB6F704D7C8E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).